Somatic mutation profile of tumor specimen TCGA-77-8143-01A (aliquot TCGA-77-8143-01A-11D-2244-08) from TCGA case TCGA-77-8143, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.0 years (27,772 days).
Specimen TCGA-77-8143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c0497cc-206f-47f6-8dca-fea1047252dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8143-10A (Blood Derived Normal), aliquot TCGA-77-8143-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1671882-4f3e-47e0-846f-ed3b69200204

The open-access MAF lists 162 somatic variants for this specimen: 125 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 34, Nonsense Mutation 8, Frame Shift Del 3, RNA 2, Splice Region 1, Intron 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 36/47 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1111457, COSV64291669, COSV64295080, COSV64295612; called by muse, mutect2, varscan2
- ABCC8 | c.3907G>C p.D1303H | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100216885; called by muse, mutect2, varscan2
- ADAMTS19 | c.1400G>C p.S467T | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99176804; called by muse, mutect2, varscan2
- ADGRG4 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99794908; called by muse, mutect2, varscan2
- ALG10B | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs905309907, COSV100439843; called by muse, mutect2, varscan2
- ANKRD11 | c.2821A>G p.R941G | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99968728; called by muse, mutect2, varscan2
- AP4S1 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99364157; called by muse, mutect2, varscan2
- ARFGAP3 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV99605197; called by muse, varscan2
- ARFGAP3 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs746663640, COSV54314191; called by muse, varscan2
- ARID2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs766610841, COSV57617341; called by muse, mutect2, varscan2
- ARL4A | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100775895; called by muse, mutect2, varscan2
- ASNS | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99446106; called by muse, mutect2, varscan2
- ASTN1 | c.3341T>C p.L1114P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100705857; called by muse, mutect2, varscan2
- ATRNL1 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782808054, COSV100744628; called by muse, mutect2, varscan2
- BCL6B | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 86/111 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99546510; called by muse, mutect2, varscan2
- C11orf65 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as COSV101262755; called by muse, mutect2, varscan2
- C3orf38 | c.802A>C p.I268L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100007352; called by muse, mutect2, varscan2
- C8orf82 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99430600; called by muse, mutect2
- CAMKK2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100242737; called by muse, mutect2, varscan2
- CCNP | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV55688846; called by muse, mutect2, varscan2
- CDH10 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100050658; called by muse, mutect2, varscan2
- CEP162 | c.2893A>G p.M965V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100002543; called by muse, mutect2, varscan2
- CILP | c.1796C>A p.A599D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV99973047; called by muse, mutect2, varscan2
- CKAP4 | c.1740A>T p.L580F | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100952422; called by muse, mutect2, varscan2
- CLCNKB | c.501C>A p.G167= | Splice Region (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100990214; called by muse, mutect2, varscan2
- CMBL | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 97/173 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99686953; called by muse, mutect2, varscan2
- CSMD3 | c.4278C>G p.I1426M (on ENST00000297405 / NM_001363185.1; = p.I1322M on NM_052900.3) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52173467, COSV99829158; called by muse, mutect2, varscan2
- CX3CR1 | c.434A>T p.H145L | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100843152; called by muse, mutect2, varscan2
- DCAF13 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99885116; called by muse, mutect2, varscan2
- DIO2 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV101375840; called by muse, varscan2
- DIP2C | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99790808; called by muse, mutect2, varscan2
- DMXL2 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99196114; called by muse, mutect2, varscan2
- DSP | c.2850T>G p.I950M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs727502999, COSV101131204; ClinVar: uncertain significance; called by muse, mutect2
- ENTPD3 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100088540; called by muse, mutect2, varscan2
- EPC1 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99552724; called by muse, mutect2, varscan2
- FAM135B | c.4145C>T p.A1382V | Missense Mutation (SNP) | VAF 151/513 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99421164; called by muse, mutect2, varscan2
- FAM135B | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867471938, COSV52703558; called by muse, mutect2, varscan2
- FASN | c.6676C>T p.P2226S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV100147534; called by muse, mutect2, varscan2
- FBN2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99325966; called by muse, mutect2, varscan2
- G3BP1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1206326690, COSV62366962; called by muse, mutect2
- GABBR1 | c.1509G>T p.Q503H | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100589536; called by muse, mutect2, varscan2
- GARRE1 | c.2803G>C p.V935L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100209179, COSV55099543; called by muse, mutect2, varscan2
- GASK1B | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1350161602, COSV99647432; called by muse, mutect2, varscan2
- GASK1B | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56706010, COSV99647436; called by muse, mutect2, varscan2
- GLI1 | c.2849C>A p.P950H | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV99953846; called by muse, mutect2, varscan2
- GOT1L1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56876112; called by muse, mutect2, varscan2
- GPR82 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100220556; called by muse, mutect2, varscan2
- GRIN2B | c.1523T>C p.M508T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101662973; called by muse, mutect2, varscan2
- GRM1 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); catalogued as rs1293559679, COSV99265028; called by muse, mutect2
- GRM5 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV100550987; called by muse, mutect2, varscan2
- HSP90AA1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs745418872, COSV99355141; called by muse, mutect2, varscan2
- HTR2B | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.688); catalogued as COSV99295209; called by muse, mutect2, varscan2
- IBTK | c.1295G>A p.W432* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs1356901409, COSV100090317; called by muse, mutect2, varscan2
- ILDR2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99613495; called by muse, mutect2, varscan2
- INTS6L | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV100878052; called by muse, mutect2, varscan2
- KAT7 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 50/71 reads (70%) | catalogued as COSV99371666; called by muse, mutect2, varscan2
- KCNJ3 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99715460; called by muse, mutect2, varscan2
- KDM5B | c.4362G>T p.E1454D | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs374839807, COSV99350295; called by muse, mutect2, varscan2
- KLK13 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV50066926, COSV99335221; called by muse, mutect2, varscan2
- LRRTM4 | c.554T>A p.F185Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV101297471; called by muse, mutect2, varscan2
- MAGEE1 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100819341, COSV63910782; called by muse, mutect2, varscan2
- MAP3K9 | c.961A>C p.I321L | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101173538; called by muse, mutect2, varscan2
- MGAT5 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs547381763, COSV56095090, COSV56102677; called by muse, mutect2, varscan2
- MRGPRX4 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV100049682; called by muse, mutect2, varscan2
- NELL1 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100120079; called by muse, mutect2, varscan2
- NFATC1 | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.851); catalogued as COSV99501079; called by muse, mutect2, varscan2
- NID2 | c.2796C>G p.D932E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99356186; called by muse, mutect2, varscan2
- NLRP8 | c.2224G>C p.V742L | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99404956, COSV99405238; called by muse, mutect2, varscan2
- NRAP | c.3460C>A p.L1154M (on ENST00000359988 / NM_001322945.2; = p.L1119M on NM_006175.4) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV100748353; called by muse, mutect2, varscan2
- NUP205 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 49/90 reads (54%) | catalogued as COSV53666303, COSV99606665; called by muse, mutect2, varscan2
- NUP205 | c.2906G>T p.G969V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs147722934; called by muse, mutect2, varscan2
- OLR1 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100376331; called by muse, mutect2, varscan2
- OR5D18 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100450600; called by muse, mutect2, varscan2
- OR6B1 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101281642; called by muse, mutect2, varscan2
- OR6C3 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV101110325; called by muse, mutect2, varscan2
- OSMR | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV99952904; called by muse, mutect2, varscan2
- P2RY10 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409014; called by muse, mutect2, varscan2
- PCLO | c.4501G>T p.D1501Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100429466; called by muse, mutect2, varscan2
- PDK3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64793916; called by muse, mutect2, varscan2
- PFKL | c.1394T>C p.M465T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.216); catalogued as rs1349059402, COSV100827054; called by muse, mutect2, varscan2
- PON3 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV99672349; called by muse, mutect2, varscan2
- PPIP5K1 | c.4241C>A p.S1414Y (on ENST00000396923; = p.S1389Y on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV100288335; called by muse, mutect2, varscan2
- PPP2R3A | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99386708; called by muse, mutect2, varscan2
- PTPRB | c.3413G>T p.S1138I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs1194339348, COSV99716491, COSV99718365; called by mutect2, varscan2
- QRICH1 | c.986A>C p.H329P | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100676721; called by muse, mutect2, varscan2
- QSOX2 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs918490315, COSV100699726; called by muse, mutect2, varscan2
- ROBO3 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV67299334; called by muse, mutect2, varscan2
- RPN1 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99956951; called by muse, mutect2, varscan2
- RXFP3 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs745728220, COSV57503925; called by muse, mutect2
- SALL1 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51753871, COSV99172504; called by muse, mutect2, varscan2
- SALL1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99172511; called by muse, mutect2, varscan2
- SERPINA5 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100291531, COSV100291845; called by muse, mutect2, varscan2
- SERPINB10 | c.491-1G>T p.X164_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99448960; called by muse, mutect2, varscan2
- SGCE | c.1342C>T p.P448S (on ENST00000647096; = p.P412S on NM_003919.3) | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99722296; called by muse, mutect2, varscan2
- SLC22A9 | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99654851; called by muse, mutect2, varscan2
- SLC25A14 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV99502350; called by muse, mutect2, varscan2
- SRGAP1 | c.2982G>T p.E994D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV100754445; called by muse, mutect2, varscan2
- SSMEM1 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99927642; called by muse, mutect2, varscan2
- ST3GAL2 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | PolyPhen probably damaging (0.999); catalogued as COSV100735627; called by muse, mutect2, varscan2
- SYNE1 | c.23339A>C p.N7780T (on ENST00000367255 / NM_182961.4; = p.N7709T on NM_033071.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99557627; called by muse, mutect2, varscan2
- TAF6 | c.1988C>G p.A663G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as rs1562916017, COSV100612647; called by muse, mutect2, varscan2
- TET2 | c.2630A>G p.D877G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1553914301, COSV99481859; called by muse, mutect2
- THADA | c.5431G>A p.D1811N | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV100368201; called by muse, mutect2, varscan2
- TLE4 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs989319452, COSV99511588; called by mutect2, varscan2
- TLR3 | c.734T>C p.L245S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99710892; called by muse, mutect2, varscan2
- TMEM119 | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101219446, COSV67188948; called by muse, mutect2, varscan2
- TMPRSS6 | c.928T>C p.Y310H | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs916375086, COSV100695568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMTC3 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898028; called by muse, mutect2, varscan2
- TPCN2 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 42/278 reads (15%) | catalogued as rs369199583; called by muse, mutect2, varscan2
- TRIM10 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100939660, COSV64999649; called by muse, mutect2, varscan2
- WASHC3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99527420; called by muse, mutect2, varscan2
- WDR7 | c.3898G>T p.A1300S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.07); catalogued as COSV99589005; called by muse, mutect2, varscan2
- WTAP | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100603291; called by muse, mutect2, varscan2
- ZC2HC1A | c.858A>T p.K286N | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99803876; called by muse, mutect2, varscan2
- ZFHX4 | c.10486T>A p.S3496T | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.099); catalogued as COSV99259912; called by muse, mutect2, varscan2
- ZNF33A | c.281G>T p.S94I (on ENST00000458705 / NM_006974.3; = p.S95I on NM_006954.2) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV56725472; called by muse, mutect2, varscan2
- ZNF804A | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56444738, COSV56447834; called by muse, mutect2, varscan2
- ZRANB3 | c.1345G>T p.G449* | Nonsense Mutation (SNP) | VAF 108/211 reads (51%) | catalogued as COSV99923074; called by muse, mutect2, varscan2
- AJUBA | c.94_105delinsC p.G32Rfs*10 | Frame Shift Del (DEL) | VAF 20/35 reads (57%) | called by pindel, varscan2*
- CLEC16A | c.506_507del p.F169Cfs*14 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGKV1-16 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- IGKV3D-15 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MUC2 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TP53 | c.730_736del p.G244* | Frame Shift Del (DEL) | VAF 42/66 reads (64%) | called by mutect2, pindel, varscan2
- CASKIN1 | c.2044C>T p.L682= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100399281; called by muse, mutect2, varscan2
- CCDC178 | c.2196A>G p.R732= (on ENST00000383096 / NM_001105528.3; = p.R694= on NM_198995.3) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55773530; called by muse, mutect2, varscan2
- CKMT1B | c.756C>T p.H252= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100294498, COSV55853152; called by muse, mutect2, varscan2
- FAM53C | c.501C>T p.V167= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99524284; called by muse, mutect2
- FGGY | c.1452C>A p.S484= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs114601020, COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- FTH1 | c.87C>T p.L29= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1395393794, COSV99861252; called by muse, mutect2
- GLP2R | c.1177T>C p.L393= | Silent (SNP) | VAF 13/298 reads (4%) | catalogued as COSV99301730; called by muse, mutect2
- GOLM1 | c.18C>T p.N6= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs775196459, COSV99974287; called by muse, mutect2, varscan2
- GPR158 | c.2985C>A p.T995= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100893036, COSV100893078; called by muse, mutect2, varscan2
- GRIA4 | c.1191C>A p.V397= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV99229962; called by muse, mutect2, varscan2
- ITPR2 | c.2868G>A p.G956= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV101189889; called by muse, mutect2
- LARGE1 | c.234C>T p.A78= | Silent (SNP) | VAF 81/128 reads (63%) | catalogued as rs1163573856, COSV100504946; called by muse, mutect2, varscan2
- LUM | c.240T>C p.H80= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99898923; called by muse, mutect2, varscan2
- NCAM1 | c.2205C>G p.L735= (on ENST00000316851 / NM_181351.5; = p.L725= on NM_000615.7) | Silent (SNP) | VAF 118/183 reads (64%) | catalogued as COSV100377243; called by muse, mutect2, varscan2
- NOS2 | c.3018G>A p.R1006= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100569550; called by muse, mutect2, varscan2
- NUDT16 | c.445C>A p.R149= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV100720814, COSV63248311; called by muse, mutect2, varscan2
- OR2Z1 | c.642C>T p.I214= | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as rs782808201, COSV60693161; called by muse, mutect2, varscan2
- PIK3R4 | c.1209T>G p.L403= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100768313; called by muse, mutect2, varscan2
- PSG11 | c.861T>C p.F287= | Silent (SNP) | VAF 82/127 reads (65%) | catalogued as COSV100105610; called by muse, mutect2, varscan2
- RPS9 | c.570C>T p.D190= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs142681896, COSV57190636; called by muse, mutect2, varscan2
- SAMD9L | c.3138G>T p.V1046= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs1195994018, COSV100560499; called by muse, mutect2, varscan2
- SEC14L1 | c.2070C>T p.S690= | Silent (SNP) | VAF 177/245 reads (72%) | catalogued as COSV101170925; called by muse, mutect2, varscan2
- SGCZ | c.69C>T p.T23= | Silent (SNP) | VAF 73/125 reads (58%) | catalogued as COSV101167773; called by muse, mutect2, varscan2
- SLC35E4 | c.801C>G p.L267= | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as COSV100299170; called by muse, mutect2, varscan2
- SLC4A3 | c.513C>T p.D171= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs757698492, COSV56092984; called by muse, mutect2, varscan2
- SLITRK3 | c.1791C>A p.L597= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99578802; called by muse, mutect2, varscan2
- ST3GAL2 | c.837G>T p.T279= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100735628, COSV100735695; called by muse, mutect2, varscan2
- ST3GAL4 | c.357C>T p.R119= (on ENST00000392669 / NM_001254758.1; = p.R115= on NM_006278.3) | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as COSV99917350; called by muse, mutect2, varscan2
- SYNE1 | c.21930G>T p.L7310= (on ENST00000367255 / NM_182961.4; = p.L7239= on NM_033071.3) | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99557633; called by muse, mutect2, varscan2
- TGFBR3 | c.2205C>G p.A735= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs902448362, COSV99282645; called by muse, mutect2, varscan2
- TNR | c.1236C>A p.A412= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV54886635, COSV99688531; called by muse, mutect2
- TRAPPC11 | c.2277A>G p.L759= | Silent (SNP) | VAF 77/145 reads (53%) | catalogued as rs199804527, COSV100591757; called by muse, mutect2, varscan2
- TTN | c.63123G>A p.E21041= (on ENST00000591111; = p.E13617= on NM_003319.4) | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV60026879; called by muse, mutect2, varscan2
- TTN | c.26475G>A p.S8825= (on ENST00000591111; = p.S7898= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs368081453; ClinVar: uncertain significance; called by muse, mutect2
- DCHS2 | n.7718T>C | RNA (SNP) | VAF 25/45 reads (56%) | catalogued as COSV100601434; called by muse, mutect2, varscan2
- DENND10P1 | n.758C>A | RNA (SNP) | VAF 39/59 reads (66%) | called by muse, mutect2, varscan2
- PDLIM5 | c.920+563C>A | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100523461; called by muse, mutect2, varscan2
